Somatic mutation profile of tumor specimen TARGET-40-NAAGJK-01A (aliquot TARGET-40-NAAGJK-01A-01D) from TARGET case TARGET-40-NAAGJK, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.3 years (5,595 days).
Specimen TARGET-40-NAAGJK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d5b5eab-a92d-44cc-925a-50acec0a3789.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJK-10B (Blood Derived Normal), aliquot TARGET-40-NAAGJK-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51cd2e29-5768-4608-8e73-f99944396efd

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTLL7 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs769393930, COSV53081636; called by muse, mutect2, varscan2
- TMEM132D | c.895G>C p.V299L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SDK1 | c.3537C>T p.S1179= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs200756610; called by muse, mutect2, varscan2
